Surgical pathology report (de-identified scan), TCGA case TCGA-WA-A7H4, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Schleswig-Holstein, specimen TCGA-WA-A7H4-01A (Primary Tumor).

[page 1 of 2]
Date of tumor procurement:

Name

Study Subject ID:

Material / Macroscopy

7. Surgical tumor specimen, marker suture: toward the base of the tongue – thick and long, toward the lateral floor of the mouth – thick and short, edge of the tongue toward the anterior – thin and long. One grayish beige, soft, nodular piece of excised tissue 4 x 3 x 2 cm in size, one side covered with mucous membrane. The mucosal surface exhibits a 1.7 x 0.8-cm, slightly nodular, broad ulcerated lesion with minimum distances to the resection margins of 1.2 cm to the edge of the tongue toward the anterior, 0.6 cm to the lateral floor of the mouth, 1.3 cm to the base of the tongue, and 1 cm to the medial. A straight cut was applied to the specimen at the edge of the lateral floor of the mouth. From the anterior to the lateral resection margin to the base of the tongue = blue, from the base of the tongue to the medial resection margin to the anterior = red, to the depth = black. The cut surfaces below the mucosa ulceration reveal a grayish white, unclearly delimited tumor growing 0.5 cm deep with a minimum distance of 0.6 cm to the lateral resection margin, 0.9 cm to the medial resection margin, and 0.9 cm to the deep resection margin. a = lamella at the edge of the tongue toward the anterior, b - f = lamellated from the edge of the tongue to the anterior to the base of the tongue, g = lamella at the edge of the base of the tongue.

10. Healthy mucosa: piece of excised tissue 0.7 x 0.5 x 0.3 cm in size. Halved and embedded in toto.

Microscopy

(7 blocks, H&E)

7. Cross-sections of excised tissue show margins which are covered by a dysplasia-free, multilayer, non-keratinizing squamous epithelium; in the depth with sections of skeletal muscle and numerous normal serous glands. In the central lamellae, the mucosa is partially superficially ulcerated and scabbed-over; the underlying tissue shows extensive formations of atypical squamous epithelium, which superficially exhibit a rather solid, and in the depth a rather ragged, partially reticular growth pattern. The cells vary in size, exhibit irregular configurations, and have a pale eosinophilic cytoplasm and markedly pleomorphic, partially significantly enlarged nuclei with prominent nucleoli and numerous, partially atypical mitoses. Recurring evidence of polynuclear cells. Varying degrees of keratinization.

The tumor cell structures are surrounded by a varying desmoplastic stroma reaction and a moderately mixed cellular inflammatory infiltrate mainly composed of lymphocytes and plasma cells as well as individual neutrophil granulocytes.

ICD O-3

Carcinoma, squamous cell keratinizing NOS 8071/3

Site: Tongue NOS C02.9

9/4/13

[page 2 of 2]
Name

No evidence of angioinvasion or infiltration of the perineural sleeves. In d, the tumor cell structures extend right up to the lateral/deep soft tissue resection margin marked with black ink. Other resection margins are tumor-free.

10. Cross-sections of excised tissue were covered with a dysplasia-free, multilayer, partially keratinizing squamous epithelium. In the keratinous lamellae, repeated detection of nuclear residues found. In addition, there is a small, mixed cellular inflammatory infiltrate composed of lymphocytes, plasma cells, and individual neutrophil granulocytes. No evidence of fungal hyphae in the PAS stain.

Diagnosis

7. Piece of tissue excised from the tongue with a 3-cm, superficially ulcerated, poorly differentiated keratinizing squamous cell carcinoma.

10. Tumor-free tissue excised from the mucosa with hyperparakeratosis and low-grade chronic recurrent acute inflammation.

ICD-10 Discrepancy		✓

Source: NCI Genomic Data Commons file 892ead6f-8d5f-40fb-96f2-25857796e6b2 (TCGA-WA-A7H4.057F6DF6-9BEE-471E-8B54-FAAC4BAC58C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).